Somatic mutation profile of tumor specimen MMRF_1851_1_PB_CD138pos (aliquot MMRF_1851_1_PB_CD138pos_T3_KBS5U_L07288) from MMRF case MMRF_1851, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 63.2 years (23,097 days).
Specimen MMRF_1851_1_PB_CD138pos: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ac6d1ca4-06c4-4e93-9fa9-b1dae984c80c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1851_1_PB_CD3pos (Blood Derived Normal), aliquot MMRF_1851_1_PB_CD3pos_C5_KBS5U_L07294; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/093d2fdc-64ed-4476-ab14-c8b5a0922ddb

The open-access MAF lists 86 somatic variants for this specimen: 39 protein-altering or splice-affecting, 10 silent, 37 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, 3'UTR 26, Silent 10, Intron 8, Splice Site 2, 5'UTR 2, Frame Shift Del 1, In Frame Ins 1, Nonsense Mutation 1, Translation Start Site 1, Frame Shift Ins 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BACH2 | c.430C>T p.R144W | Missense Mutation (SNP) | VAF 120/125 reads (96%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.639); catalogued as rs1227106751; called by muse, mutect2, varscan2
- C11orf95 | c.1832C>T p.T611M | Missense Mutation (SNP) | VAF 67/117 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1565057982; called by muse, mutect2, varscan2
- DIS3 | c.1040G>A p.G347E | Missense Mutation (SNP) | VAF 112/117 reads (96%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66706787; called by muse, mutect2, varscan2
- FANCA | c.2267G>A p.R756H | Missense Mutation (SNP) | VAF 34/63 reads (54%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as rs137913973, COSV66881343; called by muse, mutect2, varscan2
- GANAB | c.1310G>A p.R437Q | Missense Mutation (SNP) | VAF 39/100 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as rs1472158539, COSV100648258; called by muse, mutect2, varscan2
- IGHJ6 | c.58T>C p.S20P | Missense Mutation (SNP) | VAF 38/48 reads (79%) | PolyPhen probably damaging (0.96); catalogued as rs368997749; called by muse, mutect2, varscan2
- INSR | c.2296G>A p.D766N | Missense Mutation (SNP) | VAF 55/104 reads (53%) | SIFT tolerated (0.52); PolyPhen benign (0.007); catalogued as rs774340801, COSV57168630; called by muse, mutect2, varscan2
- IZUMO1R | c.335C>T p.P112L (on ENST00000440961; = p.P119L on NM_001199206.3) | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as rs202165897; called by muse, varscan2
- KNDC1 | c.2693G>A p.R898H | Missense Mutation (SNP) | VAF 55/95 reads (58%) | SIFT tolerated (0.56); PolyPhen benign (0.007); catalogued as rs1462152347, COSV100465949; called by muse, mutect2, varscan2
- M1AP | c.251G>A p.G84E | Missense Mutation (SNP) | VAF 42/79 reads (53%) | SIFT tolerated (0.26); PolyPhen probably damaging (1); catalogued as COSV99303736; called by muse, mutect2, varscan2
- MUC16 | c.3908C>G p.S1303C | Missense Mutation (SNP) | VAF 37/86 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.353); catalogued as COSV67498168; called by muse, mutect2, varscan2
- PTPRF | c.2836G>A p.G946R | Missense Mutation (SNP) | VAF 112/225 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1439775308; called by muse, mutect2, varscan2
- RAB38 | c.569C>T p.P190L | Missense Mutation (SNP) | VAF 236/527 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs761810753, COSV54713351, COSV54714768; called by muse, mutect2, varscan2
- TBX18 | c.1045C>T p.R349* | Nonsense Mutation (SNP) | VAF 22/42 reads (52%) | catalogued as rs1384411524, COSV100858519; called by muse, mutect2, varscan2
- ADAM15 | c.379G>A p.A127T | Missense Mutation (SNP) | VAF 58/120 reads (48%) | SIFT tolerated (0.19); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- CATSPER4 | c.437A>G p.N146S | Missense Mutation (SNP) | VAF 61/126 reads (48%) | SIFT tolerated (0.22); PolyPhen benign (0.21); called by muse, mutect2, varscan2
- CES1 | c.905A>C p.K302T | Missense Mutation (SNP) | VAF 40/86 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- CHD2 | c.2284dup p.C762Lfs*8 | Frame Shift Ins (INS) | VAF 99/242 reads (41%) | called by mutect2, pindel, varscan2
- DCD | c.121C>A p.Q41K | Missense Mutation (SNP) | VAF 41/81 reads (51%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- DNAH8 | c.9874G>T p.A3292S | Missense Mutation (SNP) | VAF 58/108 reads (54%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.511); called by muse, mutect2, varscan2
- EML4 | c.1109A>G p.D370G | Missense Mutation (SNP) | VAF 42/77 reads (55%) | SIFT tolerated (0.21); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- EXO1 | c.586G>A p.D196N | Missense Mutation (SNP) | VAF 103/235 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- HECTD4 | c.6560T>G p.I2187S | Missense Mutation (SNP) | VAF 92/198 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- IGSF5 | c.993G>T p.E331D | Missense Mutation (SNP) | VAF 53/89 reads (60%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- KLHL30 | c.177_178del p.A60Hfs*5 | Frame Shift Del (DEL) | VAF 32/102 reads (31%) | called by mutect2, varscan2
- KRTAP4-16 | c.466C>A p.P156T | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); called by muse, mutect2, varscan2
- MTRF1L | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 16/17 reads (94%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- NOP14 | c.107T>G p.V36G | Missense Mutation (SNP) | VAF 117/279 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- NPR2 | c.3005C>T p.S1002F | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PEX6 | c.1479+1G>A p.X493_splice | Splice Site (SNP) | VAF 64/141 reads (45%) | called by muse, mutect2, varscan2
- PHC3 | c.51_53dup p.S18dup (on ENST00000494943 / NM_001308116.2; = p.S30dup on NM_024947.4) | In Frame Ins (INS) | VAF 72/175 reads (41%) | called by pindel, varscan2
- QPCTL | c.73C>A p.P25T | Missense Mutation (SNP) | VAF 38/88 reads (43%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- RPS6KA6 | c.1365+2T>C p.X455_splice | Splice Site (SNP) | VAF 70/73 reads (96%) | called by muse, mutect2, varscan2
- SNX16 | c.819A>C p.R273S | Missense Mutation (SNP) | VAF 44/165 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- SOAT2 | c.1561C>T p.H521Y | Missense Mutation (SNP) | VAF 130/255 reads (51%) | SIFT tolerated (0.32); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- SOGA3 | c.2356G>T p.V786L | Missense Mutation (SNP) | VAF 69/77 reads (90%) | SIFT tolerated (0.15); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- TOPAZ1 | c.2270G>A p.S757N | Missense Mutation (SNP) | VAF 100/211 reads (47%) | SIFT tolerated (0.53); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF417 | c.263C>T p.P88L | Missense Mutation (SNP) | VAF 61/151 reads (40%) | SIFT tolerated (0.67); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- ZNFX1 | c.1725G>C p.E575D | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT tolerated (0.59); PolyPhen benign (0); called by muse, mutect2, varscan2
- AXIN1 | c.2130G>A p.A710= | Silent (SNP) | VAF 12/33 reads (36%) | catalogued as rs749294095; called by muse, varscan2
- CR1L | c.82C>T p.L28= | Silent (SNP) | VAF 71/130 reads (55%) | called by muse, mutect2, varscan2
- ECRG4 | c.66G>A p.L22= | Silent (SNP) | VAF 21/40 reads (53%) | called by muse, mutect2, varscan2
- HERC1 | c.12420T>A p.S4140= | Silent (SNP) | VAF 77/158 reads (49%) | called by muse, varscan2
- JADE3 | c.1026C>T p.H342= | Silent (SNP) | VAF 38/42 reads (90%) | catalogued as rs1311939874; called by muse, mutect2, varscan2
- MGAM2 | c.826C>T p.L276= | Silent (SNP) | VAF 65/158 reads (41%) | catalogued as rs267601329; called by muse, mutect2, varscan2
- MYH2 | c.5319G>A p.E1773= | Silent (SNP) | VAF 80/169 reads (47%) | catalogued as COSV55447999; called by muse, mutect2, varscan2
- PTPRU | c.2880C>T p.A960= | Silent (SNP) | VAF 70/157 reads (45%) | called by muse, mutect2
- SDK1 | c.1065G>A p.A355= | Silent (SNP) | VAF 54/122 reads (44%) | catalogued as rs769886680, COSV67361051, COSV67369890; called by muse, mutect2, varscan2
- SZT2 | c.6108C>T p.F2036= (on ENST00000634258 / NM_001365999.1; = p.F1979= on NM_015284.4) | Silent (SNP) | VAF 65/130 reads (50%) | called by muse, mutect2, varscan2
- ARHGAP42 | c.*440del | 3'UTR (DEL) | VAF 4/32 reads (13%) | catalogued as rs202022806, COSV53974750; called by pindel, varscan2
- C2CD2 | c.*897G>A | 3'UTR (SNP) | VAF 34/79 reads (43%) | called by muse, mutect2, varscan2
- CAPN7 | c.*355T>C | 3'UTR (SNP) | VAF 71/147 reads (48%) | called by muse, mutect2, varscan2
- CD8B2 | c.620+2848C>G | Intron (SNP) | VAF 131/274 reads (48%) | called by muse, mutect2, varscan2
- CEMIP2 | c.3194+51T>A | Intron (SNP) | VAF 34/59 reads (58%) | called by muse, mutect2, varscan2
- COL21A1 | c.2091+138A>G | Intron (SNP) | VAF 25/40 reads (63%) | called by muse, mutect2, varscan2
- DYNC2LI1 | c.321-1229C>T | Intron (SNP) | VAF 32/61 reads (52%) | called by muse, mutect2, varscan2
- FAM135B | c.*344A>G | 3'UTR (SNP) | VAF 69/104 reads (66%) | catalogued as rs1197522551; called by muse, mutect2, varscan2
- GFRA1 | c.*547A>G | 3'UTR (SNP) | VAF 44/80 reads (55%) | catalogued as rs944479638; called by muse, mutect2, varscan2
- GLI2 | c.*952G>A | 3'UTR (SNP) | VAF 97/216 reads (45%) | catalogued as rs914764088; called by muse, mutect2, varscan2
- GPAT4 | c.*2875T>A | 3'UTR (SNP) | VAF 19/41 reads (46%) | called by muse, varscan2
- GSTCD | c.1240+32009C>T | Intron (SNP) | VAF 13/166 reads (8%) | catalogued as rs1442780331; called by muse, mutect2
- HMX3 | c.*406T>G | 3'UTR (SNP) | VAF 9/17 reads (53%) | called by muse, mutect2, varscan2
- KIF20B | c.*763A>T | 3'UTR (SNP) | VAF 173/318 reads (54%) | called by muse, mutect2, varscan2
- KLHL36 | c.*1327_*1330dup | 3'UTR (INS) | VAF 39/87 reads (45%) | called by mutect2, pindel, varscan2
- MAP3K13 | c.*414C>G | 3'UTR (SNP) | VAF 43/106 reads (41%) | called by muse, mutect2, varscan2
- MTA1 | c.190+205T>C | Intron (SNP) | VAF 113/176 reads (64%) | called by muse, mutect2, varscan2
- PCDHB4 | c.*542C>G | 3'UTR (SNP) | VAF 35/78 reads (45%) | called by muse, mutect2, varscan2
- PCSK7 | c.*2C>G | 3'UTR (SNP) | VAF 33/86 reads (38%) | called by muse, mutect2, varscan2
- PDK3 | c.*727G>C | 3'UTR (SNP) | VAF 9/9 reads (100%) | called by muse, mutect2
- PHF24 | c.*764T>A | 3'UTR (SNP) | VAF 27/59 reads (46%) | called by muse, mutect2, varscan2
- PRKCG | c.-177C>G | 5'UTR (SNP) | VAF 90/195 reads (46%) | called by muse, mutect2, varscan2
- RAB17 | c.435+569C>T | Intron (SNP) | VAF 58/92 reads (63%) | catalogued as rs149153125; called by muse, mutect2, varscan2
- RBM33 | c.*4181T>G | 3'UTR (SNP) | VAF 34/70 reads (49%) | catalogued as rs1034338301; called by muse, varscan2
- SATB2 | c.*708C>A | 3'UTR (SNP) | VAF 28/68 reads (41%) | catalogued as rs1421395197; called by muse, varscan2
- SATB2 | c.*675G>T | 3'UTR (SNP) | VAF 28/60 reads (47%) | called by muse, varscan2
- SESN3 | c.*3842G>C | 3'UTR (SNP) | VAF 30/62 reads (48%) | catalogued as rs908104148; called by muse, mutect2, varscan2
- SIX1 | c.-245A>G | 5'UTR (SNP) | VAF 22/46 reads (48%) | called by muse, mutect2, varscan2
- SLC16A2 | c.*2122G>A | 3'UTR (SNP) | VAF 36/38 reads (95%) | called by muse, mutect2, varscan2
- SLC6A17 | c.*1575G>A | 3'UTR (SNP) | VAF 41/83 reads (49%) | called by muse, mutect2, varscan2
- SPA17 | c.*538G>A | 3'UTR (SNP) | VAF 8/17 reads (47%) | called by muse, mutect2, varscan2
- SPRED1 | c.*2870C>A | 3'UTR (SNP) | VAF 61/115 reads (53%) | called by muse, mutect2, varscan2
- SYT9 | c.*606A>T | 3'UTR (SNP) | VAF 59/128 reads (46%) | called by muse, mutect2, varscan2
- TMEM33 | c.*3048A>G | 3'UTR (SNP) | VAF 29/57 reads (51%) | called by muse, mutect2, varscan2
- TMOD2 | c.*823T>C | 3'UTR (SNP) | VAF 42/85 reads (49%) | called by muse, mutect2, varscan2
- ZNF720P1 | n.148A>T | RNA (SNP) | VAF 56/119 reads (47%) | called by muse, mutect2, varscan2
- ZNF85 | c.229+2211C>T | Intron (SNP) | VAF 4/12 reads (33%) | called by muse, mutect2
